Somatic mutation profile of tumor specimen TCGA-KS-A4I5-01A (aliquot TCGA-KS-A4I5-01A-11D-A257-08) from TCGA case TCGA-KS-A4I5, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 49.2 years (17,963 days).
Specimen TCGA-KS-A4I5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a0372f6-65a6-4eea-b7ec-7ed43d7493a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KS-A4I5-11A (Solid Tissue Normal), aliquot TCGA-KS-A4I5-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8986b077-65c2-472b-83e6-8ce510ade0f4

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BDH1 | c.640G>T p.G214W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64018814; called by muse, mutect2, varscan2
- FAT3 | c.10040G>C p.S3347T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0.039); catalogued as COSV53124989; called by muse, mutect2, varscan2
- HTR3B | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs758490357, COSV52745574; called by muse, mutect2, varscan2
- PSMA4 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50384676; called by muse, mutect2, varscan2
- SPTA1 | c.6982C>A p.P2328T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63754842; called by muse, mutect2, varscan2
- DLC1 | c.1296A>C p.G432= | Silent (SNP) | VAF 50/103 reads (49%) | catalogued as COSV52309367; called by muse, mutect2, varscan2
- PCDHGA3 | c.1887G>A p.A629= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as rs1173189539, COSV53966716; called by muse, mutect2, varscan2
